Surgical pathology report (de-identified scan), TCGA case TCGA-FL-A1YN, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii - Normal Study, specimen TCGA-FL-A1YN-11A (Solid Tissue Normal).

[page 1 of 4]
Surgical Pathology Report

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED]
DOB: [REDACTED]
Gender: F
Physician(s): [REDACTED]
cc: [REDACTED]

Client: [REDACTED]
Location: [REDACTED]

Accession #: [REDACTED]
Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

History/Clinical Dx: Pelvic mass

Postoperative Dx: Pending pathology examination

ICD - O - 3 not applicable.

Specimen(s) Received:

A: Left ovarian mass
B: Uterus, cervix

*Normal path from non-cancer patient.
for 11/11/11*

DIAGNOSIS:

- A. Left ovarian mass: Benign mucinous cystadenoma
- B. Uterus and cervix:
- Cervix: Unremarkable
- Endometrium: Proliferative with benign endometrial polyps
- Myometrium: Leiomyomata, Intramural

Intraoperative Consultation:

- A. Frozen Section Interpretation: Mucinous tumor, benign

Gross Description

- A. Received fresh labeled "left ovarian mass" is a single segment of soft tan membranous tissue with mucoid material, 232 grams, 13.0 x 10.0 x 2.0 cm. There is a thick mucin attached to the specimen. The inner lining is smooth, with one area friable and slightly hemorrhagic, measuring 2.5 x 2.0 x 0.6 cm. Representative sections are submitted in eight cassettes after two frozen sections.
- B. Received: In formalin, is a previously opened unoriented uterus and cervix
- Labeled: Uterus, cervix
- Weight: 72 grams
- Size: 8.6 x 7.2 x 2.8 cm
- Appearance
- Serosal surface: Smooth, with ragged areas
- Cervix: Grossly unremarkable
- Endometrium: 0.1 cm in thickness, with no polyps or solid areas grossly identified
- Myometrium: 1.8 cm in thickness. No areas of adenomyosis grossly identified. There are multiple myomas, largest measuring up to 1.3 x 1.0 x 1.0 cm. The myomas have whorled white cut surfaces.

Regulatory Statement:

The following statement may be applicable to some of the reagents/antibodies used in developing the above report: This test was developed and its performance characteristics determined by [REDACTED] not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as a [REDACTED] or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 4]
[REDACTED] Surgical Pathology Report [REDACTED]

Other: None

KEY TO CASSETTES:

B1 - Cervix
B2 - Lower uterine segment, full thickness
B3-B4 - Endo/myometrium, full thickness
B5 - Myomas

Microscopic Description

A&B. The microscopic findings support the above diagnoses.

[REDACTED]

[page 3 of 4]
Surgical Pathology Report

Patient Name: [REDACTED]

Med. Rec. #: [REDACTED]

DOB: [REDACTED]

Gender: F

Physician(s): [REDACTED]

cc: [REDACTED]

Client: [REDACTED]

Location: [REDACTED]

Accession #: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

History/Clinical Dx: Abdominal mass, rectal bleeding

Postoperative Dx: Pending pathology examination

Specimen(s) Received:

A: Distal esophageal biopsies x 3

B: Colon biopsies x 2, (at 65CM)

C: Colon biopsies x 2, (at 45CM)

DIAGNOSIS:

A. Gastric biopsy:

No pathologic abnormality

B. Colon 65 cm:

Crypt abscesses, reactive glandular changes and granulomas inflammation consistent with Crohn's colitis

C. Colon biopsy 45 cm:

Active colitis, mild

Gross Description

- A. Received in formalin labeled "distal esophagus x3 biopsy" consists of multiple pale tan, slightly hemorrhagic tissue fragments measuring in aggregate 0.9 x 0.3 x 0.2 cm. Submitted in toto.
- B. Received in formalin labeled "colon biopsy x2 at 65 cm" consists of multiple white, pale tan, slightly hemorrhagic tissue fragments measuring in aggregate 0.8 x 0.3 x 0.2 cm. Submitted in toto.
- C. Received in formalin labeled "colon biopsy x2 at 45 cm" consists of multiple white, pale tan, slightly hemorrhagic tissue fragments measuring in aggregate 0.5 x 0.3 x 0.2 cm. Submitted in toto.

Microscopic Description

A-C. The microscopic findings support the above diagnoses.

Regulatory Statement:

The following statement may be applicable to some of the reagents/antibodies used in developing the above report: This test was developed and its performance characteristics determined by [REDACTED] and its use is not intended for clinical purposes. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as a substitute for clinical research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 4 of 4]
[REDACTED]

Non-Gynecological Cytology Report

Patient Name: [REDACTED]

Med. Rec. #: [REDACTED]

DOB: [REDACTED]

Gender: F

Physician(s): [REDACTED]

cc: [REDACTED]

Client: [REDACTED]

Location: [REDACTED]

Accession #: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

Source of Specimen(s):

Pelvic washings

Clinical History:

Pelvic Mass

[REDACTED]

CYTOLOGIC DIAGNOSIS:

Pelvic Washings:

Specimen Adequacy:

Satisfactory for evaluation.

Interpretation:

Negative for malignancy

Smears and cell block show benign mesothelial cells

Gross Description:

Specimen consists of approx. 30cc of dark red bloody material unfixed fluid.

2 CLH/PPPI prepped slides

1 Cell block

2 Pap stained

[REDACTED]

Regulatory Statement:

The following statement may be applicable to some of the reagents/antibodies used in developing the above report. This test was developed and its performance characteristics determined. It has been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[REDACTED]

Source: NCI Genomic Data Commons file 45765ce0-5c9f-41de-8cf8-fc62bebe6b51 (TCGA-FL-A1YN.BA22BA6E-3DEF-4354-A52C-19B405A349FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).